Gene-level copy-number profile of tumor specimen REBC-AF8T-TTP1 from REBC case REBC-AF8T, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-AF8T-TTP1: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a3ac35b7-f153-45c2-a857-1ab85524184a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-AF8T-NB1-SC217007 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/f8938fae-52b5-44e3-a669-4fd610e3015c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 110; copy number 2: 57,861; copy number 3: 386; copy number 4: 5; copy number 5: 4.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:125,966,777–125,968,085, 1 gene: RPSAP37.
- chr6:85,257,328–85,257,694, 1 gene: AL122016.1.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr9:80,563,571–80,565,962, 2 genes: MTCO1P51, MTND2P9.
- chr10:38,783,004–38,783,108, 1 gene: AL590623.1.
- chr11:50,409,042–54,725,816, 12 genes: AC024405.1, OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P.
- chr11:56,790,206–56,820,422, 2 genes (within-gene range 0–2): OR5G4P, OR5G5P.
- chr12:37,575,587–37,576,384, 1 gene: ZNF970P.
- chr19:27,638,483–27,794,005, 4 genes (within-gene range 0–2): ERVK-28, AC112702.1, LINC00662, AC006504.1.
- chr22:15,282,557–15,350,043, 5 genes: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.

Autosomal genes at a single copy (total copy number 1): 95. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
